Gene-level copy-number profile of tumor specimen ALCH-B2VU-TTP1-A from ALCHEMIST case ALCH-B2VU, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 59.8 years (21,842 days).
Specimen ALCH-B2VU-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 84bc8164-d1df-43bd-aea2-3b9776e64f83.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B2VU-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,240 have no estimate.
https://portal.gdc.cancer.gov/files/878f3168-e391-4276-bd85-7926622a9199

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 18; copy number 1: 6,551; copy number 2: 40,183; copy number 3: 8,390; copy number 4: 3,154; copy number 5: 80; copy number 7: 2; copy number 8: 5.

Homozygous deletions (total copy number 0; autosomes only): 18 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:116,792,085–117,060,799, 4 genes: GPRC6A, RFX6, RPS29P13, RNA5SP214.
- chr9:40,883,634–40,883,763, 1 gene: AL353626.2.
- chr10:65,054,460–65,055,003, 1 gene: NEK4P3.
- chr10:101,226,195–101,229,794, 1 gene (within-gene range 0–2): LBX1.
- chr11:69,809,968–69,819,416, 1 gene: FGF3.
- chr18:12,093,843–12,129,764, 3 genes (within-gene range 0–1): ANKRD62, RNU6-324P, SDHDP1.
- chr19:7,617,439–7,629,545, 2 genes (within-gene range 0–2): MIR6792, XAB2.
- chr22:18,501,794–18,530,573, 5 genes: FAM247B, GGTLC3, Metazoa_SRP, AC023490.3, TMEM191B.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 87 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:248,623,557–248,655,528, 3 genes, copy number 8: OR2T11, OR2T35, OR2T27.
- chr5:58,198–1,851,497, 65 genes, copy number 5 (broad region; genes not listed).
- chr7:74,650,231–74,789,376, 4 genes, copy number 5: GTF2I, AC211433.1, PHBP15, NCF1.
- chr11:3,276,045–3,289,642, 2 genes, copy number 7: NDUFA5P8, AC109309.2.
- chr17:18,432,051–18,475,920, 4 genes, copy number 5–8 (within-gene range 2–8): KRT16P1, KRT16P4, AL353997.1, AL353997.4.
- chr17:18,476,737–18,494,945, 1 gene, copy number 8: LGALS9C.
- chr22:15,805,263–16,141,872, 8 genes, copy number 5: BMS1P22, AP000525.1, DUXAP8, NBEAP3, TOMM40P2, AP000522.1, AC145543.1, U6.

Autosomal genes at a single copy (total copy number 1): 5,913. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
